TARGET case TARGET-10-PARKZX — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7ca8100c-856c-5369-b1eb-8837d2b86eea

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 12 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 13.0 years (4,739 days); Year of diagnosis: 2007; Days to last follow up: 3,087 days (8.5 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 1,371 days (3.8 years); Days to first event: 1,371 days (3.8 years); First event: Relapse.
- Days to follow up: 3,087 days (8.5 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Positive.
- Trisomy 4: Positive.
- Day 0: Leukocytes 74.7 ×10³/µL.
- Day 8: Bone Marrow blast count 30%; Minimal Residual Disease (Flow Cytometry) 0.6%.
- Day 15: Bone Marrow blast count 1%.
- Day 29: Bone Marrow blast count 2%; Minimal Residual Disease (Flow Cytometry) 0.0025%.

Biospecimens (2 samples)
- Sample TARGET-10-PARKZX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARKZX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PARKZX-09A-01D:
- Blast %: yes many

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 3087
- WBC at Diagnosis: 74.7
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 0.6
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.0025
- MRD Day 29 Sensitivity: 0.0025
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Positive
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 30
- BMA Blasts Day 15: 1
- BMA Blasts Day 29: 2
- Karyotype: 56,XX,+X,+4,+6,+8,+10,+11,+14,+14,+21,+21[20]
- Down Syndrome: No
- DNA Index: 1.243
- Alternate Therapy: Chemotherapy; Other
- Alternate Therapy Other: Maintenance therapy was extended 6 months from initial end of therapy. Cart-T cell therapy
- Cell of Origin: B Cell ALL
